Gene-level copy-number profile of tumor specimen C3N-00339-02 from CPTAC case C3N-00339, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 45.4 years (16,577 days).
Specimen C3N-00339-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 277c9443-1e1f-4a49-bbd9-f9db73cb1e6b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00339-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/cc296417-15f9-4417-9581-37fc035dec52

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 17,512; copy number 3: 879; copy number 4: 37,645; copy number 5: 623; copy number 6: 1,212; copy number 7: 75; copy number 8: 37; copy number 9: 303; copy number 11: 2; copy number 18: 12; copy number 24: 75.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 392 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes, copy number 18: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr8:127,686,343–127,742,951, 2 genes, copy number 11: CASC11, MYC.
- chr11:55,262,155–56,297,471, 75 genes, copy number 24 (broad region; genes not listed).
- chr12:564,296–684,127, 6 genes, copy number 9: NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455.
- chr20:52,051,663–64,327,972, 289 genes, copy number 9 (broad region; genes not listed).
- chr21:8,986,999–9,129,752, 8 genes, copy number 9: MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
